Somatic mutation profile of tumor specimen TCGA-AG-3901-01A (aliquot TCGA-AG-3901-01A-01W-1073-09) from TCGA case TCGA-AG-3901, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 67.1 years (24,502 days).
Specimen TCGA-AG-3901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d65aa09-94fd-472c-bbdd-b08b26b32f12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3901-10A (Blood Derived Normal), aliquot TCGA-AG-3901-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75f4313c-38ab-43da-8459-3c443d0ca349

The open-access MAF lists 70 somatic variants for this specimen: 49 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 20, Nonsense Mutation 3, Frame Shift Ins 2, RNA 1, Splice Site 1, Splice Region 1, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.2234C>T p.T745M | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs28939720, CM131121, CM992150; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 44/170 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- PIK3CA | c.1031T>G p.V344G | Missense Mutation (SNP) | VAF 24/98 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1057519941, COSV55876054, COSV55895486, COSV55974473; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.202T>A p.Y68N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs398123317, CM061927, CM131940, CM981667, COSV64289561, COSV64292590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAD4 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 24/105 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61685209, COSV61685537, COSV61689602; called by muse, mutect2, varscan2
- AFAP1 | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs149064401; called by muse, mutect2, varscan2
- APC | c.3124_3125insT p.S1042Mfs*6 | Frame Shift Ins (INS) | VAF 40/218 reads (18%) | catalogued as COSV57397699, COSV99967952; called by mutect2, pindel, varscan2
- BCORL1 | c.3268C>T p.R1090* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV54389244; called by muse, mutect2, varscan2
- BRWD3 | c.3751C>G p.L1251V | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.358); catalogued as COSV100955812, COSV64754236; called by muse, mutect2, varscan2
- CASD1 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs371554475; called by muse, mutect2, varscan2
- CBWD6 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1355900359; called by muse, mutect2
- CXorf21 | c.256A>C p.T86P | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100973270, COSV66763402; called by muse, mutect2, varscan2
- CYLC1 | c.1075A>G p.K359E | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as COSV61416494; called by muse, mutect2, varscan2
- DDX27 | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404464320, COSV65611107; called by muse, mutect2, varscan2
- DGKG | c.1116G>A p.T372= | Splice Region (SNP) | VAF 6/39 reads (15%) | catalogued as rs533768857, COSV53973809; called by muse, mutect2
- DIAPH3 | c.3443G>A p.R1148K | Missense Mutation (SNP) | VAF 66/318 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV64966674; called by muse, mutect2
- DOCK9 | c.4948C>T p.R1650W (on ENST00000376460 / NM_001366676.2; = p.R1651W on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs371892069; called by muse, mutect2, varscan2
- DYNC2H1 | c.10927G>T p.E3643* | Nonsense Mutation (SNP) | VAF 74/497 reads (15%) | catalogued as COSV62108396; called by muse, mutect2, varscan2
- EIF2B1 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as COSV99434579; called by muse, mutect2
- FOXJ3 | c.1228C>T p.L410F | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.202); catalogued as rs1351192002, COSV62365677; called by muse, mutect2, varscan2
- GFRA1 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs752981166, COSV62611549; called by muse, mutect2
- GRM3 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777582336, COSV64480607; called by muse, mutect2, varscan2
- HOXA5 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as COSV56075132; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 79/360 reads (22%) | catalogued as COSV100781466, COSV61148187; called by muse, varscan2
- IMPDH1 | c.1531C>T p.R511W (on ENST00000470772 / NM_001142573.2; = p.R597W on NM_000883.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs530357590, COSV58318289; ClinVar: uncertain significance; called by muse, mutect2
- KCNH4 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52921511; called by muse, mutect2, varscan2
- KCNT2 | c.3056G>A p.R1019Q | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs773845489, COSV54068516; called by muse, mutect2, varscan2
- MAGEE2 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV64897547, COSV64898631; called by muse, mutect2
- MCM10 | c.1564C>A p.L522M (on ENST00000484800 / NM_182751.3; = p.L521M on NM_018518.5) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV66337135; called by muse, mutect2, varscan2
- MUC6 | c.5153C>T p.P1718L | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); catalogued as COSV70151116; called by muse, mutect2, varscan2
- NIPBL | c.6205A>G p.I2069V | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV56967867; called by muse, mutect2, varscan2
- NLRP3 | c.2285C>T p.T762M | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs759466218, COSV60231886; called by muse, mutect2, varscan2
- PIGR | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as COSV62905194; called by muse, mutect2, varscan2
- PSMD1 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58084114; called by muse, mutect2, varscan2
- SERPIND1 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.011); catalogued as COSV53141277; called by muse, mutect2, varscan2
- SLC24A2 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs757988035, COSV53862991; called by muse, mutect2, varscan2
- SLC35D2 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53565072; called by muse, mutect2
- SLC5A10 | c.514T>C p.S172P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV58762712; called by muse, mutect2, varscan2
- SOGA1 | c.2176G>T p.A726S | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV99414004; called by muse, mutect2
- TCTN3 | c.1673G>C p.G558A | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV56452174; called by muse, mutect2
- TDRD6 | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs756938796, COSV60178722, COSV60179062; called by muse, mutect2, varscan2
- TNIP2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs545493843, COSV59570339; called by muse, mutect2
- UGGT2 | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV65026141; called by muse, mutect2, varscan2
- ZNF423 | c.1301A>T p.E434V (on ENST00000563137 / NM_001379286.1; = p.E426V on NM_015069.4) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV99281774; called by muse, mutect2
- ZNF521 | c.2899C>T p.R967W | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs931158045, COSV64132497, COSV64132735; called by muse, mutect2, varscan2
- APC | c.4240del p.V1414* | Frame Shift Del (DEL) | VAF 49/217 reads (23%) | called by mutect2, pindel, varscan2
- SMC1B | c.1185dup p.L396Tfs*9 | Frame Shift Ins (INS) | VAF 67/362 reads (19%) | called by pindel, varscan2
- TLR3 | c.1207_1208insTTGTTT p.F401_V402dup | In Frame Ins (INS) | VAF 16/120 reads (13%) | called by mutect2, pindel, varscan2
- U2SURP | c.1379_1379+37del p.X460_splice | Splice Site (DEL) | VAF 13/77 reads (17%) | called by mutect2, pindel
- ABCA5 | c.1518G>A p.E506= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as COSV67019398; called by muse, mutect2
- ATXN1 | c.1398C>T p.S466= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs144916658; called by muse, mutect2, varscan2
- C22orf23 | c.240G>A p.S80= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs746977617, COSV50778814; called by muse, mutect2, varscan2
- CHRNA9 | c.1206C>T p.N402= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as rs144758556; called by muse, mutect2, varscan2
- CLNK | c.417C>T p.S139= | Silent (SNP) | VAF 42/227 reads (19%) | catalogued as rs371671172; called by muse, mutect2, varscan2
- DLGAP3 | c.915G>A p.S305= | Silent (SNP) | VAF 51/291 reads (18%) | catalogued as rs781101151, COSV52395341, COSV52396785, COSV52398573; called by muse, mutect2, varscan2
- DOCK11 | c.3036G>A p.R1012= | Silent (SNP) | VAF 46/224 reads (21%) | catalogued as COSV52248680; called by muse, mutect2, varscan2
- GSG1L | c.726C>A p.T242= (on ENST00000447459 / NM_001109763.2; = p.T87= on NM_144675.2) | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV66582977; called by muse, mutect2, varscan2
- KAT5 | c.714C>T p.G238= | Silent (SNP) | VAF 19/177 reads (11%) | catalogued as COSV57730604; called by muse, mutect2, varscan2
- KCNMB3 | c.150A>G p.P50= | Silent (SNP) | VAF 32/188 reads (17%) | catalogued as COSV58571734; called by muse, mutect2, varscan2
- NCBP1 | c.507T>C p.Y169= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV64317524; called by muse, mutect2, varscan2
- PAPPA2 | c.375G>A p.P125= | Silent (SNP) | VAF 85/414 reads (21%) | catalogued as rs1267448610, COSV62773629; called by muse, mutect2, varscan2
- PCDHA12 | c.810C>T p.D270= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as rs1227830598, COSV100250622; called by muse, mutect2, varscan2
- PKD1L2 | c.51C>A p.A17= | Silent (SNP) | VAF 33/155 reads (21%) | catalogued as COSV61420290; called by muse, mutect2, varscan2
- RBM45 | c.1305C>T p.A435= (on ENST00000616198 / NM_001365579.1; = p.A433= on NM_152945.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs759464587, COSV53721177, COSV53722755; called by muse, mutect2, varscan2
- SCN1A | c.3750G>A p.T1250= (on ENST00000303395 / NM_001202435.3; = p.T1239= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs771494149, COSV57690648; called by muse, mutect2, varscan2
- SHC3 | c.891C>T p.I297= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs759425983, COSV65438419; called by muse, mutect2, varscan2
- TTN | c.58455A>T p.V19485= (on ENST00000591111; = p.V12061= on NM_003319.4) | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV60387243; called by muse, mutect2, varscan2
- ZFP82 | c.1029C>T p.C343= | Silent (SNP) | VAF 77/396 reads (19%) | catalogued as rs112210948, COSV67566273; called by muse, mutect2, varscan2
- ZNF425 | c.57G>A p.S19= | Silent (SNP) | VAF 20/183 reads (11%) | catalogued as rs560790723, COSV65201861; called by muse, mutect2, varscan2
- DIRC1 | n.491C>G | RNA (SNP) | VAF 85/383 reads (22%) | catalogued as rs766619816, COSV57370582; called by muse, mutect2, varscan2
